Surgical pathology report (de-identified scan), TCGA case TCGA-AY-6196, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-6196-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

Colon, right, resection

Tumor Histologic Type: Adenocarcinoma with prominent mucinous and signet ring cell features; see comment.

Histologic Grade: poorly differentiated

Tumor Location: ascending colon

Depth of Invasion:

-Through muscularis propria into the pericolic soft tissue

Lymphovascular Invasion: present, extensive

Perineural Invasion: not identified

Margins:

Proximal margin: Negative for malignancy.

Distal margin: Negative for malignancy

Mesenteric margin: Negative for malignancy

Distance of carcinoma from closest margin (specify): tumor is 2.0 cm from the mesenteric margin.

Regional Lymph Nodes: Twelve of fourteen lymph nodes positive for metastatic poorly differentiated adenocarcinoma, 1.0 cm in greatest dimension, extracapsular extension present (12/14).

Additional pathologic findings: - Appendix with mucin and tumor cells within periappendiceal soft tissue and extending into muscularis propria of appendix.

- Severe acute and chronic serositis with adhesions.

AJCC PATHOLOGIC TNM STAGE: pT3 pN2b

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Immunohistochemical stains for MLH1, MSH2, and MSH6 are performed. The tumor demonstrates appropriate nuclear staining for all three markers which is the normal phenotype and which does not support a diagnosis of hereditary non-polyposis colorectal cancer. Microsatellite instability testing will be performed by the [REDACTED] Lab and reported separately.

Clinical History:

right colon cancer.

Gross Description:

Specimen fixation: formalin

Parts of bowel received/ Specimen length: colon (17 cm in length, 6.7 cm in circumference); ileum (10.7 cm in length, 3.4 cm in circumference); appendix with a length of 3.5 cm and a diameter of 0.9 cm

Orientation: The distal colonic margin is inked black, the ileal margin is inked blue, the surrounding fat over the tumor is inked green.

Tumor location: 4.2 cm from blue inked margin and 12.7 cm from black inked margin.

[page 2 of 3]
Gross appearance of tumor: Ulcerated, hemorrhagic, firm, tan/white

Tumor dimensions: 7.5 cm x 5.5 cm x 5.0 cm

Circumferential growth: 50% of luminal circumference involved

Gross depth of invasion: Tumor invades grossly into the fat. There are multiple separate tumor nodules/candidate lymph nodes which are present in the pericolonic fat and measure up to 3.5 cm.

Gross evidence of perforation through visceral peritoneum: no

Luminal obstruction: approximately 70%

Bowel circumference at tumor site: 4.5 cm

Gross distance of tumor from margins: 4.2 cm from the blue inked margin, 12.7 cm from the black inked margin, 2.0 cm from perpendicular soft tissue margin

Lymph nodes: per block summary

Other remarkable findings: multiple tumor nodules and surrounding fat; The appendix wall is thickened (0.4 cm) and the mucosal surface is tan. The tip of the appendix is dilated with a maximum diameter of 1.1 cm. The internal surface is tan/pink and regular.

Tissue submitted for special investigation: yes, to Tissue Procurement

Digital photograph taken: not taken

Block summary:

(Inking scheme: ileal margin=blue, colonic margin=black)

A1 - ileal margin, en face (inked blue)

A2 - colonic margin, en face (inked black)

A3 - soft tissue/vascular margins overlying tumor

A4 - representative sections of appendix (cross sections)

A5 - representative section of tumor, perpendicular to mucosa

A6 - representative section of tumor (perpendicular to mucosa) with pericolonic fat

A7 - tumor with pericolonic fat

A8 - tumor nodule with pericolonic fat (inked green)

A9 - tumor nodule with pericolonic fat (inked green)

A10 - representative section of tumor

A11 - representative section of tumor with pericolonic fat

A12 - representative section of tumor

A13 - three lymph node fragments/candidate tumor satellites

A14 - two lymph node fragments

A15 - two lymph node fragments

A16 - one lymph node fragment

A17 - two lymph node fragments

A18 - two lymph node fragments

A19 - one lymph node fragment, bisected

A20 - one lymph node fragment, bisected

A21 - one lymph node fragment, bisected

A22 - two lymph node fragments

A23-A24 - one lymph node fragment, trisected

A25 - two lymph node fragments

A26 - three lymph node fragments

A27 - four lymph node fragments

A28 - tip of appendix, longitudinal

[page 3 of 3]
Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

For cases in which immunostains are performed, the following applies: Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the [REDACTED]
[REDACTED] These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] alified to perform high complexity clinical laboratory testing.

Signature

[REDACTED]

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 4fad3143-8901-46d4-ba1d-87e6c7cd164e (TCGA-AY-6196.E6E1533F-49E4-4E98-AE67-540B48BEDDFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).